TCGA case TCGA-MB-A5Y9 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Minnesota. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e5608743-59c4-4846-96b5-b3d36efbed85

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (2)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2012; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis percent: 5; Necrosis present: Yes.
   Pathology details: Measurement type: Pathologic; Tumor burden: 26.5.
   Pathology details: Measurement type: Radiologic; Tumor burden: 8.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 12; Tumor width measurement: 10.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 4; Tumor width measurement: 4.
2. Prior malignancy of the head, face or neck (histology not recorded by GDC). Age at diagnosis: 90 years or older (exact value withheld by GDC); Days to diagnosis: -11,877 days (-32.5 years).

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 45.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MB-A5Y9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 620 mg.
  Slide TCGA-MB-A5Y9-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MB-A5Y9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-MB-A5Y9-10A, TCGA-MB-A5Y9-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Positive; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic length: 4; Lesion radiologic width: 4; Lesion pathologic depth: 4.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Head - face or neck, NOS; Days from index date to other malignancy diagnosis: -11878.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -11878.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 252 days; disease-specific survival: no event (censored), 252 days; progression-free interval: no event (censored), 252 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MB-A5Y9-01A-11D-A29M-01): tumor purity 0.21, ploidy 2.32, whole-genome doublings 0.
